Somatic mutation profile of tumor specimen TCGA-A5-A0GM-01A (aliquot TCGA-A5-A0GM-01A-11W-A062-09) from TCGA case TCGA-A5-A0GM, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 53.3 years (19,452 days).
Specimen TCGA-A5-A0GM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44e88db0-115f-4a58-a174-5b13dc14ca72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0GM-10A (Blood Derived Normal), aliquot TCGA-A5-A0GM-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2808c4db-cd39-410e-be04-ae6b0ce29e66

The open-access MAF lists 44 somatic variants for this specimen: 36 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 28, Silent 8, Nonsense Mutation 3, Frame Shift Ins 2, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 28/65 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 33/68 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 106/256 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS4 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); catalogued as rs372130629, COSV63487407; called by muse, mutect2, varscan2
- ANKRD16 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs140831926; called by muse, mutect2, varscan2
- ARHGEF40 | c.3412C>T p.R1138W | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs759147946, COSV53881013; called by muse, mutect2, varscan2
- ATP2B1 | c.2846C>A p.A949D | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.202); catalogued as COSV53808485; called by muse, mutect2, varscan2
- BRWD1 | c.4759G>A p.V1587I | Missense Mutation (SNP) | VAF 77/153 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1442327886, COSV60897037; called by muse, mutect2, varscan2
- CTCF | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 69/159 reads (43%) | catalogued as COSV50472407; called by muse, mutect2, varscan2
- CTCF | c.781+1G>A p.X261_splice | Splice Site (SNP) | VAF 65/139 reads (47%) | catalogued as COSV50472422; called by muse, mutect2, varscan2
- ELAVL3 | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 98/209 reads (47%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV52951814; called by muse, mutect2, varscan2
- FRMPD1 | c.4343del p.P1448Qfs*29 | Frame Shift Del (DEL) | VAF 14/35 reads (40%) | catalogued as rs1326968411; called by mutect2, pindel, varscan2
- GLIPR2 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 90/163 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as rs749643384, COSV65029357; called by muse, mutect2, varscan2
- HAO1 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs866866590, COSV66491549; called by muse, mutect2
- HP | c.1121T>C p.I374T | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63326037; called by muse, mutect2, varscan2
- HYAL1 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs143791794; called by muse, mutect2
- IGFBP7 | c.743G>C p.C248S | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55273735; called by muse, mutect2, varscan2
- KDM2B | c.13C>G p.Q5E | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV65641776; called by muse, mutect2, varscan2
- MAGEC1 | c.3244A>G p.R1082G | Missense Mutation (SNP) | VAF 117/246 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as COSV53574150; called by muse, mutect2, varscan2
- MED12 | c.3412C>G p.R1138G | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61339953, COSV61342433; called by muse, mutect2, varscan2
- NELFB | c.1541C>T p.T514M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as rs752643955, COSV58025294; called by muse, mutect2, varscan2
- NGFR | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.954); catalogued as rs143067054; called by muse, mutect2, varscan2
- NLRP2 | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs370185803; called by muse, mutect2, varscan2
- NRXN1 | c.3460A>G p.I1154V | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58459285; called by muse, mutect2, varscan2
- RBBP6 | c.1447C>T p.Q483* | Nonsense Mutation (SNP) | VAF 67/138 reads (49%) | catalogued as COSV60505719; called by muse, mutect2, varscan2
- SEC13 | c.766A>T p.K256* (on ENST00000350697 / NM_183352.3; = p.K259* on NM_030673.4) | Nonsense Mutation (SNP) | VAF 44/113 reads (39%) | catalogued as COSV61601671, COSV61601839; called by muse, mutect2, varscan2
- SEC22C | c.693C>A p.F231L | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.359); catalogued as COSV52565616, COSV99827529; called by muse, mutect2, varscan2
- SPATS2 | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as rs1270631876, COSV58919386; called by muse, mutect2, varscan2
- TBC1D8 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as rs773935600, COSV65210014; called by muse, mutect2, varscan2
- UTRN | c.1532C>T p.T511I | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.841); catalogued as COSV62337485; called by muse, mutect2, varscan2
- ZC3H7B | c.857G>A p.S286N | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs755073188, COSV60962361; called by muse, mutect2, varscan2
- ZFYVE26 | c.2728C>A p.Q910K | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV61329457; called by muse, mutect2, varscan2
- ZNF215 | c.704C>T p.T235I | Missense Mutation (SNP) | VAF 25/614 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV53493447; called by muse, mutect2
- ARID1A | c.2209_2210dup p.M737Ifs*6 | Frame Shift Ins (INS) | VAF 34/108 reads (31%) | called by mutect2, pindel, varscan2
- ARID1A | c.4764_4776del p.A1589Gfs*19 | Frame Shift Del (DEL) | VAF 57/145 reads (39%) | called by mutect2, pindel, varscan2
- NRDE2 | c.2295dup p.L766Tfs*7 | Frame Shift Ins (INS) | VAF 46/125 reads (37%) | called by mutect2, pindel, varscan2
- AMHR2 | c.810C>T p.R270= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV57686007; called by muse, mutect2, varscan2
- CYP2S1 | c.1131G>T p.R377= | Silent (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2
- EFTUD2 | c.1194G>A p.E398= | Silent (SNP) | VAF 80/151 reads (53%) | catalogued as rs369383512; called by muse, mutect2, varscan2
- H2BW1 | c.405C>T p.A135= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV54220050, COSV54220458; called by muse, mutect2
- IGF2R | c.2805T>C p.S935= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as rs1377000985, COSV63629671; called by muse, mutect2, varscan2
- MANEA | c.324C>T p.Y108= | Silent (SNP) | VAF 90/212 reads (42%) | catalogued as COSV62589797; called by muse, mutect2, varscan2
- PCDHA1 | c.381C>T p.N127= | Silent (SNP) | VAF 55/121 reads (45%) | catalogued as rs782041938, COSV65374812; called by muse, mutect2, varscan2
- TEP1 | c.5562G>A p.G1854= | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as COSV52993939; called by muse, mutect2, varscan2
